TCGA case TCGA-XF-AAMJ — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of Southern California. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8f10e006-531a-49ac-b51b-df3fdcb20929

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 70 years; Vital status: Dead; Days to death: 1,670 days (4.6 years).

Diagnoses (2)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 70.7 years (25,838 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Extracapsular extension: Focal; Extracapsular extension present: Yes; Lymph nodes positive: 0; Lymph nodes tested: 44; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 82 days; Days to treatment end: 143 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Days to treatment start: 82 days; Days to treatment end: 143 days; Treatment outcome: Complete Response; Drug category: Platinum.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 173 days; Days to treatment end: 204 days; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Regional Site.
2. Prior malignancy of the prostate gland (histology not recorded by GDC). Age at diagnosis: 63.1 years (23,059 days); Days to diagnosis: -2,779 days (-7.6 years); AJCC pathologic N: N0.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -2,779 days (-7.6 years); Treatment anatomic sites: Prostate.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,670 days (4.6 years); Disease response: Tumor Free.
- Karnofsky performance status: 90.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 55 kg; Height: 157 cm; BMI: 22.3.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.
- Occupation type: Other Health Professionals.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XF-AAMJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 480 mg.
  Slide TCGA-XF-AAMJ-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-XF-AAMJ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XF-AAMJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Occupation current: Pharmacy Technician; Occupation primary: Pharmacy Technician; Occupation primary industry: Retail Pharmacy; Tobacco smoking history indicator: 1; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: Yes; Incidental prostate cancer indicator: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate.
- Other malignancy form, Surgery: Other malignancy surgery type: prostatectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,670 days; disease-specific survival: no event (censored), 1,670 days; disease-free interval: no event (censored), 1,670 days; progression-free interval: no event (censored), 1,670 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XF-AAMJ-01A-11D-A42D-01): tumor purity 0.24, ploidy 3.54, whole-genome doublings 1.
